Gene-level copy-number profile of tumor specimen TCGA-HZ-A49I-01A from TCGA case TCGA-HZ-A49I, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.9 years (28,454 days).
Specimen TCGA-HZ-A49I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.fe38f857-411e-4f79-810b-14ff55321abd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-A49I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10961648-d039-4417-9f25-d9812b3908cd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 11,365; copy number 3: 332; copy number 4: 47,026; copy number 5: 356; copy number 6: 369; copy number 8: 30; copy number 9: 8; copy number 10: 221; copy number 14: 5; copy number 16: 19; copy number 22: 8; copy number 38: 15; copy number 62: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-A49I-01A-12D-A26H-01): tumor purity 0.34, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 333 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,212,421–24,967,504, 12 genes, copy number 10–14: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2.
- chr12:38,646,822–41,072,415, 27 genes, copy number 16–22 (within-gene range 3–22): CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr12:70,515,870–71,118,247, 8 genes, copy number 9: PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr17:15,062,087–16,569,204, 72 genes, copy number 38–62 (within-gene range 2–62) (broad region; genes not listed).
- chr19:37,007,857–41,207,539, 213 genes, copy number 10 (broad region; genes not listed).
- chr19:41,221,426–41,222,051, 1 gene, copy number 10: AC011510.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
